Gene-level copy-number profile of tumor specimen TCGA-12-1090-01A from TCGA case TCGA-12-1090, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.5 years (21,377 days).
Specimen TCGA-12-1090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.ea62ace8-fdd6-4826-9abb-a84ab521517d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-1090-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed83522a-fe96-4478-bedb-7ffecfc05f24

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 5; copy number 3: 70; copy number 4: 184; copy number 5: 54,433; copy number 6: 10; copy number 8: 742; copy number 9: 1,219; copy number 10: 3,099; copy number 11: 6; copy number 12: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-12-1090-01): tumor purity 0.9, ploidy 2.17, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 39 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:176,119,545–176,361,807, 12 genes (within-gene range 0–4): AC139491.5, AC139491.4, AC139491.6, AC139491.2, AC139491.8, AC139493.2, AC139493.1, SIMC1, BRCC3P1, KIAA1191, AC138956.1, AC138956.2.
- chr5:176,620,082–177,022,633, 10 genes: SNCB, MIR4281, EIF4E1B, TSPAN17, AC113391.1, AC113391.2, LINC01574, UNC5A, HK3, UIMC1.
- chr5:178,237,618–178,730,659, 11 genes (within-gene range 0–3): COL23A1, AC136601.2, AC136601.1, RN7SL646P, AC008659.1, CLK4, RN7SKP70, AC113348.3, AC113348.1, AC113348.2, ZNF354A.
- chr9:5,629,025–6,008,482, 6 genes (within-gene range 0–5): RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,771,296–7,853,512, 5 genes, copy number 11: VAMP3, Z98884.2, PER3, Z98884.1, UTS2.
- chr1:8,424,645–8,435,013, 1 gene, copy number 11: RERE-AS1.
- chr1:70,660,657–71,489,976, 10 genes, copy number 12 (within-gene range 5–12): CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1, AL031429.2, ZRANB2-AS1, ZRANB2, MIR186, ZRANB2-AS2.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
